CCDI case PBCSJL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/b7c5181a-3c35-477f-9d4c-6cf6c440048e

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Mixed type rhabdomyosarcoma: ICD-O-3 morphology code: 8902/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 13.2 years (4,833 days).

Biospecimens (3 samples)
- Sample 0DY8KB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DY8KI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DY8KN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
